Somatic mutation profile of tumor specimen ALCH-AESI-TTP1-A (aliquot ALCH-AESI-TTP1-A-3-0-D-A667-36) from ALCHEMIST case ALCH-AESI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.1 years (21,203 days).
Specimen ALCH-AESI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50a877a9-70b7-49af-a17b-233f88487c4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AESI-NB1-A (Blood Derived Normal), aliquot ALCH-AESI-NB1-A-1-0-D-A667-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7251666-7f28-44b3-9876-2ac98df8f240

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, Nonsense Mutation 4, 3'UTR 3, Nonstop Mutation 1, Frame Shift Del 1, RNA 1, Intron 1, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DBT | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 44/351 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768389398, CM104303; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 240/784 reads (31%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.403T>C p.C135R | Missense Mutation (SNP) | VAF 46/225 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519975, COSV52674321, COSV52706302, COSV52827707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CD1C | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs775935078, COSV100939373, COSV63805841; called by muse, mutect2
- CDH4 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.453); catalogued as rs1051676; called by muse, mutect2
- COL2A1 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV61532230; called by muse, mutect2, varscan2
- COL4A3 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 28/708 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); catalogued as COSV67415602; called by muse, mutect2
- HPN | c.922G>T p.V308L | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1461452097; called by muse, mutect2
- MCHR2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs267600747, COSV56000697; called by muse, mutect2
- MROH7 | c.338C>G p.S113* | Nonsense Mutation (SNP) | VAF 31/176 reads (18%) | catalogued as COSV59870229; called by muse, mutect2, varscan2
- NXPE1 | c.814G>T p.E272* (on ENST00000424269; = p.E130* on NM_152315.5) | Nonsense Mutation (SNP) | VAF 9/174 reads (5%) | catalogued as COSV52628784; called by muse, mutect2
- OR4Q2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs1282000710, COSV101607677; called by muse, mutect2
- RAI14 | c.1902G>T p.M634I | Missense Mutation (SNP) | VAF 85/530 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV54293158; called by muse, mutect2, varscan2
- RYR2 | c.13183C>T p.P4395S | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as COSV63668823; called by muse, mutect2
- SEMA5A | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 59/458 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs771230983, COSV101227354; called by muse, mutect2, varscan2
- ACAD11 | c.1403G>T p.C468F | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKRD34B | c.1005C>A p.C335* | Nonsense Mutation (SNP) | VAF 69/367 reads (19%) | called by muse, mutect2, varscan2
- ASPM | c.4444C>G p.R1482G | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- CCT2 | c.178T>C p.S60P | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- CITED4 | c.555A>G p.*185Wext*69 | Nonstop Mutation (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- EIF2S2 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); called by muse, mutect2
- ITGAM | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRRK2 | c.610_613dup p.Y205* | Frame Shift Ins (INS) | VAF 82/638 reads (13%) | called by mutect2, pindel
- NR2F2 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 15/282 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- NXF3 | c.713A>T p.K238M | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.195); called by muse, mutect2
- PDZRN3 | c.1661C>A p.T554N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, varscan2
- PLCH1 | c.4423C>T p.Q1475* (on ENST00000340059 / NM_001130960.2; = p.Q1467* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/308 reads (6%) | called by muse, mutect2
- PRMT6 | c.190_193del p.R64Sfs*32 | Frame Shift Del (DEL) | VAF 13/87 reads (15%) | called by mutect2, pindel*
- TBC1D29P | n.2722C>T | Splice Region (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- ZNF337 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ANK1 | c.1398G>A p.K466= | Silent (SNP) | VAF 20/582 reads (3%) | called by muse, mutect2
- ARHGEF3 | c.411G>A p.L137= | Silent (SNP) | VAF 46/410 reads (11%) | catalogued as COSV56330175; called by muse, mutect2, varscan2
- FAM217B | c.555T>G p.L185= | Silent (SNP) | VAF 16/526 reads (3%) | called by muse, mutect2
- HMCN1 | c.1944C>T p.N648= | Silent (SNP) | VAF 75/570 reads (13%) | catalogued as rs762283413, COSV54940527; called by muse, mutect2, varscan2
- MATR3 | c.2487A>G p.K829= | Silent (SNP) | VAF 14/422 reads (3%) | catalogued as COSV63080294; called by muse, mutect2
- SLITRK1 | c.1764G>A p.T588= | Silent (SNP) | VAF 40/654 reads (6%) | called by muse, mutect2
- AK2 | c.*4266T>G | 3'UTR (SNP) | VAF 40/1154 reads (3%) | called by muse, mutect2
- C1orf220 | n.546A>T | RNA (SNP) | VAF 12/277 reads (4%) | called by muse, mutect2
- CTIF | c.*236G>A | 3'UTR (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- FDFT1 | chr8:11802462 G>C | 5'Flank (SNP) | VAF 17/143 reads (12%) | called by muse, mutect2, varscan2
- KRT85 | c.*35C>T | 3'UTR (SNP) | VAF 42/201 reads (21%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85707G>A | Intron (SNP) | VAF 46/984 reads (5%) | called by muse, mutect2
